Somatic mutation profile of tumor specimen TCGA-3B-A9I1-01A (aliquot TCGA-3B-A9I1-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9I1, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 56.5 years (20,629 days).
Specimen TCGA-3B-A9I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af90a20f-4239-4fd1-a9b4-06990fb05cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9I1-10A (Blood Derived Normal), aliquot TCGA-3B-A9I1-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/237a13cf-aa8a-4ed5-b8d4-fca952693f0b

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 4, Intron 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 31/35 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 124/251 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761884012, COSV55870337, COSV99697056; called by muse, mutect2, varscan2
- ATRX | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 33/53 reads (62%) | catalogued as COSV100971578; called by muse, mutect2, varscan2
- BRAT1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100500734; called by muse, mutect2, varscan2
- GPSM2 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99915652; called by muse, mutect2, varscan2
- IGF1R | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51409290; called by muse, mutect2, varscan2
- JAK3 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1257606008, CM162295, COSV101513038; called by muse, mutect2, varscan2
- KRTAP10-9 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as COSV100555795; called by muse, mutect2, varscan2
- MMP3 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV100243056, COSV104410177; called by muse, mutect2, varscan2
- MYH11 | c.5885A>G p.D1962G | Missense Mutation (SNP) | VAF 76/122 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs112999816, COSV100260492; called by muse, mutect2, varscan2
- NTSR1 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV100980731; called by muse, mutect2, varscan2
- PFKFB4 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | PolyPhen benign (0); catalogued as rs147704999; called by muse, mutect2, varscan2
- PHRF1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213733; called by muse, mutect2, varscan2
- PLCH1 | c.1847T>C p.I616T (on ENST00000340059 / NM_001130960.2; = p.I628T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs913880847, COSV100398459; called by muse, mutect2, varscan2
- RIPOR1 | c.960G>A p.W320* (on ENST00000379312 / NM_001193522.2; = p.W316* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 21/24 reads (88%) | catalogued as COSV99243855; called by muse, mutect2, varscan2
- ROS1 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV100877795, COSV63861086; called by muse, mutect2, varscan2
- RP1 | c.5326C>A p.L1776I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99609081; called by muse, mutect2, varscan2
- RUSC1 | c.1634C>T p.P545L (on ENST00000368352 / NM_001105203.2; = p.P76L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99430381; called by muse, mutect2, varscan2
- SEC31B | c.1582C>G p.Q528E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV100947502; called by muse, mutect2, varscan2
- SLC38A10 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as rs375294715; called by muse, mutect2, varscan2
- SSX7 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs1352184981, COSV99994052; called by muse, mutect2, varscan2
- TRIML1 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100206387; called by muse, mutect2, varscan2
- TDRD3 | c.1627dup p.I543Nfs*19 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- CEP135 | c.2232T>C p.D744= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV99954940; called by muse, mutect2, varscan2
- DOCK5 | c.1563A>G p.E521= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV99378193; called by muse, mutect2
- MEI1 | c.1989G>T p.L663= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100300436; called by muse, mutect2, varscan2
- RANBP2 | c.7563T>A p.V2521= | Silent (SNP) | VAF 118/262 reads (45%) | catalogued as COSV99313503; called by muse, mutect2, varscan2
- RC3H2 | c.2535C>A p.G845= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100606151; called by muse, mutect2
- SATL1 | c.153G>A p.K51= (on ENST00000395409; = p.K238= on NM_001012980.2) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100261135; called by muse, mutect2, varscan2
- KCNH7 | c.2154+53C>T | Intron (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100034899, COSV59812217, COSV59812225; called by muse, mutect2, varscan2
- KRTAP5-6 | c.*1G>A | 3'UTR (SNP) | VAF 31/48 reads (65%) | catalogued as COSV101191790; called by muse, mutect2, varscan2
- SSPOP | n.1283G>C | RNA (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100023074, COSV50488941; called by muse, mutect2, varscan2
